Somatic mutation profile of tumor specimen TARGET-10-PARCWB-09A (aliquot TARGET-10-PARCWB-09A-01D) from TARGET case TARGET-10-PARCWB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,632 days).
Specimen TARGET-10-PARCWB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e41721e7-31e6-4049-9c7e-f2213de2a350.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCWB-10A (Blood Derived Normal), aliquot TARGET-10-PARCWB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8460343c-68d0-417e-8f45-065a316d59c8

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, 3'UTR 1, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK12 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 34/136 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71000029; called by muse, mutect2, varscan2
- GNB1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101060727; called by muse, mutect2, varscan2
- MOV10L1 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as rs374929897; called by muse, mutect2, varscan2
- P4HA3 | c.1630G>T p.D544Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59043168; called by muse, mutect2, varscan2
- TDRD5 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1162851507, COSV54242910; called by muse, mutect2, varscan2
- TNFRSF9 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV66349240; called by muse, mutect2, varscan2
- GPR39 | c.1017C>G p.I339M | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- GRID2 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MRC2 | c.1092C>T p.N364= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1478588016, COSV57645092; called by muse, mutect2
- GRM4 | c.737-88C>T | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- LYPD1 | c.*996G>A | 3'UTR (SNP) | VAF 19/50 reads (38%) | catalogued as rs975499105; called by muse, mutect2, varscan2
- NXF5 | n.341G>C | RNA (SNP) | VAF 45/70 reads (64%) | catalogued as rs1267606026; called by muse, mutect2, varscan2
- TXNDC2 | c.110-21_110-13del | Intron (DEL) | VAF 3/36 reads (8%) | catalogued as rs1324639785; called by mutect2, pindel*
